Somatic mutation profile of tumor specimen TARGET-30-PATFIN-01A (aliquot TARGET-30-PATFIN-01A-01D) from TARGET case TARGET-30-PATFIN, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.7 years (631 days).
Specimen TARGET-30-PATFIN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dd42989-c2dd-471d-adc9-4b49c1e8aea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATFIN-10A (Blood Derived Normal), aliquot TARGET-30-PATFIN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30cc84c9-0980-421c-9fd2-984a98fb79fa

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 37/97 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BPTF | c.7946G>A p.R2649H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs782594079, COSV58832726; called by muse, mutect2, varscan2
- DKC1 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV65777124; called by muse, mutect2, varscan2
- FOXR2 | c.716C>G p.T239S | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59257956; called by muse, mutect2, varscan2
- OR5F1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53545541; called by muse, mutect2
- PLEKHH1 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs780212110, COSV61281091; called by muse, mutect2, varscan2
- RYR1 | c.1105G>C p.G369R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs570010656, COSV100615325, COSV62091290; called by muse, mutect2, varscan2
- TMEM209 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV61021731; called by muse, mutect2, varscan2
- TMEM30A | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57874770; called by muse, mutect2, varscan2
- GAS2L3 | c.129T>C p.H43= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs991000312, COSV57156369; called by muse, mutect2, varscan2
